Somatic mutation profile of tumor specimen TCGA-A3-3346-01A (aliquot TCGA-A3-3346-01A-01D-0966-08) from TCGA case TCGA-A3-3346, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 68.8 years (25,118 days).
Specimen TCGA-A3-3346-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d8b6a8c-a61b-4b2a-aafa-5c3d4f062695.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3346-11A (Solid Tissue Normal), aliquot TCGA-A3-3346-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f867eafe-d303-427b-97ac-d70d57c666b9

The open-access MAF lists 99 somatic variants for this specimen: 75 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 23, Frame Shift Del 8, Frame Shift Ins 4, Splice Site 3, Nonsense Mutation 3, In Frame Del 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.405dup p.C136Mfs*44 | Frame Shift Ins (INS) | VAF 37/211 reads (18%) | catalogued as rs398123323, CI110210, COSV64293934; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ANXA4 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.642); catalogued as COSV67848612; called by muse, mutect2, varscan2
- ATP5F1B | c.1094A>G p.D365G | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51640683; called by muse, mutect2, varscan2
- CCHCR1 | c.1925G>T p.R642L | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV52536163; called by muse, mutect2, varscan2
- CELA3B | c.107T>A p.V36D | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV61404915; called by muse, mutect2, varscan2
- COL6A3 | c.8932G>A p.A2978T | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs760847135, COSV55087300; called by muse, mutect2, varscan2
- CPSF4 | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV52858584; called by muse, mutect2, varscan2
- DENND2D | c.818C>A p.A273D | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62959684; called by muse, mutect2
- DHX8 | c.2425A>G p.I809V | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.735); catalogued as COSV52255179; called by muse, mutect2, varscan2
- ESPL1 | c.5278A>T p.I1760F | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV57761395; called by muse, mutect2, varscan2
- FANCA | c.2054G>A p.R685K | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1183781456, COSV66882854; called by muse, mutect2, varscan2
- FMO5 | c.995A>T p.Y332F | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54209137; called by muse, mutect2
- GGA1 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57330686, COSV57331127; called by muse, mutect2
- GON4L | c.1789-2A>C p.X597_splice | Splice Site (SNP) | VAF 36/211 reads (17%) | catalogued as COSV55197638; called by muse, mutect2
- H2AC15 | c.235A>C p.I79L | Missense Mutation (SNP) | VAF 51/306 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV57585618, COSV57586179; called by muse, mutect2, varscan2
- HIVEP2 | c.6056C>G p.P2019R | Missense Mutation (SNP) | VAF 81/345 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50030893; called by muse, mutect2, varscan2
- HOXC6 | c.367T>C p.Y123H | Missense Mutation (SNP) | VAF 42/356 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV54537752; called by muse, mutect2, varscan2
- IFT172 | c.2428del p.E810Nfs*30 | Frame Shift Del (DEL) | VAF 27/180 reads (15%) | catalogued as rs1423464068; called by mutect2, pindel, varscan2
- IPO4 | c.2804A>C p.Q935P | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV61017638; called by muse, mutect2, varscan2
- ITPRID2 | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as COSV57474658; called by muse, mutect2, varscan2
- IZUMO2 | c.599T>G p.F200C | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV53230838; called by muse, mutect2, varscan2
- KCTD18 | c.1111C>G p.P371A | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV63344872; called by muse, mutect2, varscan2
- KIAA1522 | c.2843C>T p.S948L (on ENST00000373480 / NM_001198972.2; = p.S1007L on NM_020888.3) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53866606; called by muse, mutect2, varscan2
- KIAA1614 | c.1775A>C p.E592A | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV62551411; called by muse, mutect2, varscan2
- LARP1 | c.1513T>A p.F505I (on ENST00000518297 / NM_033551.3; = p.F428I on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/298 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60429705; called by muse, mutect2, varscan2
- LCN1 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55018910; called by muse, mutect2
- MARK1 | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65069808; called by muse, mutect2, varscan2
- MDH1 | c.923T>A p.F308Y | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51864353; called by muse, mutect2, varscan2
- MIER1 | c.1277T>G p.I426S (on ENST00000355356 / NM_001077701.3; = p.I443S on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV62531228; called by muse, mutect2, varscan2
- NAT2 | c.730T>C p.F244L | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV54062579; called by muse, mutect2, varscan2
- NCOA5 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 51/271 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51646049; called by muse, mutect2, varscan2
- NOBOX | c.838C>G p.R280G | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56196400, COSV99779790; called by muse, mutect2, varscan2
- PDXP | c.569C>G p.T190S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV53216994; called by muse, mutect2
- PIP | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 86/514 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV52121156; called by muse, mutect2
- PITRM1 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs752614003, COSV56536213; called by muse, mutect2, varscan2
- PLA2G15 | c.282C>G p.I94M | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.108); catalogued as COSV54723919; called by muse, mutect2, varscan2
- POLQ | c.6721C>T p.R2241* | Nonsense Mutation (SNP) | VAF 89/273 reads (33%) | catalogued as rs369712134, COSV51745891, COSV51764424; called by muse, mutect2, varscan2
- PPFIA2 | c.3079G>A p.E1027K | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV61033054; called by muse, mutect2, varscan2
- PPWD1 | c.88A>T p.R30* | Nonsense Mutation (SNP) | VAF 23/126 reads (18%) | catalogued as COSV54334693; called by muse, mutect2, varscan2
- PRELID1 | c.453C>G p.F151L | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs747443529, COSV57463814; called by muse, mutect2, varscan2
- RARA | c.437A>G p.Q146R | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV54194947; called by muse, mutect2, varscan2
- RCAN1 | c.482T>A p.L161Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58251070; called by muse, mutect2, varscan2
- S100A14 | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as COSV59884969; called by muse, mutect2, varscan2
- SECISBP2L | c.2364_2365insA p.V789Sfs*2 (on ENST00000559471 / NM_001193489.2; = p.V744Sfs*2 on NM_014701.4) | Frame Shift Ins (INS) | VAF 31/174 reads (18%) | catalogued as COSV99960408; called by mutect2, pindel, varscan2
- SERPINB7 | c.428A>G p.N143S | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60535045; called by muse, mutect2, varscan2
- SLC66A3 | c.323C>A p.A108D | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV54467764; called by muse, mutect2, varscan2
- SMAD9 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1483291649, COSV63205115, COSV63205817; called by muse, mutect2, varscan2
- SOBP | c.1355A>G p.H452R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58000988; called by muse, mutect2, varscan2
- SSTR1 | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as COSV57456954; called by muse, mutect2, varscan2
- TCEANC2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV52370877; called by muse, mutect2, varscan2
- THOC2 | c.3186+2T>C p.X1062_splice | Splice Site (SNP) | VAF 63/183 reads (34%) | catalogued as COSV55551569; called by muse, mutect2, varscan2
- THYN1 | c.617A>G p.Q206R | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV55541679; called by muse, mutect2
- TLN2 | c.2291G>C p.S764T | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV60892822; called by muse, mutect2, varscan2
- TMEM131 | c.2648C>T p.S883L | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as COSV51782028; called by muse, mutect2, varscan2
- TONSL | c.932T>A p.M311K | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV68048927; called by muse, mutect2, varscan2
- TP53 | c.533dup p.H178Qfs*3 | Frame Shift Ins (INS) | VAF 15/115 reads (13%) | catalogued as COSV53370106; called by mutect2, pindel, varscan2
- TUBA4A | c.148A>C p.T50P | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV50280007; called by muse, mutect2, varscan2
- TXNDC15 | c.808G>C p.G270R | Missense Mutation (SNP) | VAF 46/302 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64379962; called by muse, mutect2, varscan2
- TXNDC15 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 48/301 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64379970; called by muse, mutect2, varscan2
- USP26 | c.528G>T p.Q176H | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.894); catalogued as COSV63709296; called by muse, mutect2, varscan2
- ZGRF1 | c.1999C>A p.Q667K | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV52202260; called by muse, mutect2
- ZMYM6 | c.529A>G p.K177E | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58185001; called by muse, mutect2, varscan2
- ZYG11B | c.1061T>A p.V354E | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV53755310; called by muse, varscan2
- DNM1L | c.406del p.S136Hfs*7 | Frame Shift Del (DEL) | VAF 18/106 reads (17%) | called by mutect2, pindel, varscan2
- FAM161B | c.1578_1583delinsCTG p.E526_A528delinsD* (on ENST00000651776; = p.E463_A465delinsD* on NM_152445.3) | Nonsense Mutation (DEL) | VAF 46/225 reads (20%) | called by pindel, varscan2*
- KCNH7 | c.2614-2del p.X872_splice | Splice Site (DEL) | VAF 17/140 reads (12%) | called by mutect2, pindel, varscan2
- PARD6B | c.813_814del p.N271Kfs*10 | Frame Shift Del (DEL) | VAF 67/361 reads (19%) | called by mutect2, pindel, varscan2
- PBRM1 | c.3879del p.K1293Nfs*20 (on ENST00000296302 / NM_001366071.2; = p.K1268Nfs*20 on NM_018313.5) | Frame Shift Del (DEL) | VAF 23/131 reads (18%) | called by mutect2, pindel, varscan2
- PSMG1 | c.621del p.E207Dfs*5 | Frame Shift Del (DEL) | VAF 40/285 reads (14%) | called by mutect2, pindel, varscan2
- RASGRP1 | c.39del p.K13Nfs*14 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel
- TG | c.4024_4038del p.V1342_V1346del | In Frame Del (DEL) | VAF 46/269 reads (17%) | called by mutect2, pindel, varscan2
- TMEM68 | c.292dup p.T98Nfs*14 | Frame Shift Ins (INS) | VAF 73/417 reads (18%) | called by mutect2, pindel, varscan2
- TMPRSS6 | c.1753del p.L585Sfs*19 | Frame Shift Del (DEL) | VAF 15/111 reads (14%) | called by mutect2, pindel, varscan2
- ZBTB21 | c.3107_3115del p.A1036_F1039delinsV | In Frame Del (DEL) | VAF 43/227 reads (19%) | called by mutect2, pindel, varscan2
- ZNF846 | c.603del p.D202Tfs*16 | Frame Shift Del (DEL) | VAF 42/215 reads (20%) | called by mutect2, pindel, varscan2
- ABHD14A-ACY1 | c.156G>A p.S52= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs201635694, COSV56473154; called by muse, mutect2, varscan2
- ALOX12B | c.21G>A p.R7= | Silent (SNP) | VAF 35/161 reads (22%) | catalogued as rs1402507687, COSV59874872; called by muse, mutect2, varscan2
- CHST8 | c.234C>T p.D78= | Silent (SNP) | VAF 10/127 reads (8%) | catalogued as COSV52861297; called by muse, mutect2
- CLASP2 | c.594G>T p.V198= | Silent (SNP) | VAF 43/204 reads (21%) | catalogued as COSV56289273; called by muse, mutect2, varscan2
- CWF19L1 | c.723C>T p.F241= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV62499604; called by muse, mutect2, varscan2
- DENND2D | c.819T>G p.A273= | Silent (SNP) | VAF 9/104 reads (9%) | catalogued as COSV62959665; called by muse, mutect2
- DIP2B | c.1587T>C p.V529= | Silent (SNP) | VAF 43/187 reads (23%) | catalogued as COSV56588659; called by muse, mutect2, varscan2
- FER1L6 | c.3063C>T p.C1021= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as rs369624500, COSV67548672; called by muse, mutect2, varscan2
- FIZ1 | c.51C>T p.A17= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs189301284; called by mutect2, varscan2
- FSIP1 | c.48A>T p.S16= | Silent (SNP) | VAF 52/274 reads (19%) | catalogued as COSV63225965; called by muse, mutect2, varscan2
- H1-0 | c.423C>A p.T141= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as rs370894514, COSV50649701; called by muse, mutect2, varscan2
- HDAC1 | c.921C>T p.N307= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as rs780243739, COSV61482250; called by muse, mutect2, varscan2
- IL7R | c.444G>T p.V148= | Silent (SNP) | VAF 24/166 reads (14%) | catalogued as COSV57411144; called by muse, varscan2
- INTS2 | c.24A>C p.I8= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV52155215; called by muse, mutect2, varscan2
- LILRB5 | c.1083C>G p.A361= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as COSV60259764; called by muse, mutect2, varscan2
- MYO5A | c.3444A>C p.V1148= | Silent (SNP) | VAF 39/224 reads (17%) | catalogued as COSV62562800; called by muse, mutect2, varscan2
- NUP35 | c.447A>C p.T149= | Silent (SNP) | VAF 30/187 reads (16%) | catalogued as COSV54558749; called by muse, mutect2, varscan2
- OR1L1 | c.768C>T p.V256= (on ENST00000373686; = p.V206= on NM_001005236.3) | Silent (SNP) | VAF 98/440 reads (22%) | catalogued as COSV58936109; called by muse, mutect2, varscan2
- ORC1 | c.1476A>T p.R492= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV65364634; called by muse, mutect2, varscan2
- RASSF6 | c.846T>A p.I282= (on ENST00000342081 / NM_201431.2; = p.I250= on NM_177532.5) | Silent (SNP) | VAF 124/606 reads (20%) | catalogued as COSV56720018; called by muse, mutect2, varscan2
- RBM47 | c.1593T>C p.I531= (on ENST00000295971 / NM_001098634.2; = p.I462= on NM_019027.4) | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV55939555; called by muse, mutect2, varscan2
- SPZ1 | c.603C>T p.N201= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV57064271; called by muse, mutect2, varscan2
- TMPRSS15 | c.2412T>C p.Y804= | Silent (SNP) | VAF 41/276 reads (15%) | catalogued as rs760633326, COSV53044814; called by muse, mutect2, varscan2
- MFRP | chr11:119341574 C>A | 3'Flank (SNP) | VAF 18/79 reads (23%) | catalogued as COSV60990723, COSV60991068; called by muse, mutect2, varscan2
